Gene-level copy-number profile of tumor specimen TCGA-HZ-8636-01A from TCGA case TCGA-HZ-8636, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 58.9 years (21,501 days).
Specimen TCGA-HZ-8636-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.ce637f00-af6e-41ab-bbbe-d87905822398.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-8636-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcddf896-102c-49fb-ad03-bb96d554ed3d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 186; copy number 2: 11,219; copy number 3: 15,023; copy number 4: 25,174; copy number 5: 5,242; copy number 6: 2,684; copy number 7: 82; copy number 8: 2; copy number 10: 104; copy number 13: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-8636-01A-21D-2392-01): tumor purity 0.5, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,786,927–23,826,337, 67 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 134 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:34,457,414–36,304,924, 104 genes, copy number 10 (broad region; genes not listed).
- chr12:19,404,045–19,720,801, 1 gene, copy number 13 (within-gene range 3–13): AEBP2.
- chr12:19,508,904–21,757,857, 29 genes, copy number 13 (within-gene range 5–13): AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB.

Autosomal genes at a single copy (total copy number 1): 186. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
